HCMI case HCM-BROD-1078-C49 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myomatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b72a905b-4179-4da4-8bfb-e0287d28bab2

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Year of birth: 1971; Vital status: Alive.

Diagnoses (2)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C49.9; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Classification of tumor: primary; Age at diagnosis: 45.9 years (16,769 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IV; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: GX; Prior malignancy: no; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,271 days (3.5 years); Days to treatment end: 1,342 days (3.7 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,271 days (3.5 years); Days to treatment end: 1,398 days (3.8 years); Treatment outcome: Treatment Ongoing.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.
2. Metastasis of the connective, subcutaneous and other soft tissues (histology not recorded by GDC). ICD-10 code: C79.8; Site of resection or biopsy: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 48.7 years (17,790 days); Days to diagnosis: 1,021 days (2.8 years).

Follow-up (1 entry)
- Days to follow up: 1,462 days (4.0 years); Disease response: Stable Disease; Progression or recurrence: No.

Molecular and laboratory tests
- ALK mutation, nos: Negative.
- BRAF mutation, nos (Targeted Sequencing): Negative.
- CDKN2A mutation, nos: Negative.
- EGFR: Negative.
- GNAS mutation, nos: Negative.
- KRAS mutation, nos: Negative.
- MYCN amplification: Not Amplified.
- PIK3CA mutation, nos: Negative.
- PTEN mutation, nos: Negative.
- TP53 mutation, nos (Targeted Sequencing): Positive; Amino-acid change: R337H.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 55 kg; Height: 160 cm; BMI: 21.
- Timepoint category: Prior to Diagnosis; Comorbidities: Human Papillomavirus Infection.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Alcohol drinks per day: 1; Alcohol days per week: 5.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-1078-C49-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-1078-C49-06B-01-S1-HE: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-1078-C49-06B-01-S2-HE: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-1078-C49-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-1078-C49-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
